Somatic mutation profile of tumor specimen TARGET-40-PAPXWB-01A (aliquot TARGET-40-PAPXWB-01A-01D) from TARGET case TARGET-40-PAPXWB, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 15.3 years (5,604 days).
Specimen TARGET-40-PAPXWB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a59e999e-5a1b-4a69-bd75-eb87e4b6d6c0.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PAPXWB-10A (Blood Derived Normal), aliquot TARGET-40-PAPXWB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88933dcf-4a92-4d66-bec9-d0276eeed95a

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NNT | c.2306C>T p.S769F | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52929978; called by muse, mutect2, varscan2
- MUC16 | c.1167G>T p.W389C | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.526); called by muse, mutect2
- ZNF184 | c.1310A>C p.Q437P | Missense Mutation (SNP) | VAF 20/519 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2
- CACNA1B | c.4560G>A p.L1520= | Silent (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2, varscan2
- CAMSAP1 | c.2952A>G p.Q984= | Silent (SNP) | VAF 16/133 reads (12%) | called by muse, mutect2, varscan2
- OBSCN | c.21000C>T p.H7000= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as rs1261670819; called by muse, mutect2
- MUCL3 | c.947-759G>C | Intron (SNP) | VAF 68/862 reads (8%) | catalogued as rs140827661, COSV58518173; called by muse, mutect2
